CCDI case PBBPVL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b7396504-1edc-464d-b197-3057ced16520

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Choroid plexus carcinoma: ICD-O-3 morphology code: 9390/3; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 1.2 years (445 days).

Biospecimens (3 samples)
- Sample 0DEFHO: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DEFJC: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DEFJX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
